Somatic mutation profile of tumor specimen TARGET-10-PASYWF-03A (aliquot TARGET-10-PASYWF-03A-01D) from TARGET case TARGET-10-PASYWF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.5 years (2,022 days).
Specimen TARGET-10-PASYWF-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f57f1891-81c8-45e5-9691-10ef29d46900.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASYWF-10A (Blood Derived Normal), aliquot TARGET-10-PASYWF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed88789d-6bd5-4bc9-ab37-aa54a1aa70b4

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, Frame Shift Ins 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGFG2 | c.425_427del p.K142del | In Frame Del (DEL) | VAF 24/78 reads (31%) | catalogued as rs1295978762; called by pindel, varscan2
- APOB | c.7524G>T p.M2508I | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV51931107; called by muse, mutect2, varscan2
- FRG2 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 63/219 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs1281858577; called by muse, mutect2, varscan2
- GABRD | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs370735082; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GKN1 | c.481dup p.Y161Lfs*36 | Frame Shift Ins (INS) | VAF 45/97 reads (46%) | catalogued as rs759880395; called by mutect2, varscan2
- IGHV3-72 | c.291G>T p.K97N | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.089); catalogued as COSV101455368, COSV70409497; called by muse, mutect2, varscan2
- MSH4 | c.1067T>C p.L356S | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54200568; called by muse, mutect2, varscan2
- PLEKHM3 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.49); PolyPhen benign (0.355); catalogued as rs760143757, COSV66816239; called by muse, mutect2, varscan2
- RYR3 | c.5914C>A p.Q1972K | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV66783821; called by muse, mutect2, varscan2
- APC | c.909G>A p.R303= | Silent (SNP) | VAF 61/123 reads (50%) | called by muse, mutect2, varscan2
- TBC1D8 | c.516G>T p.V172= | Silent (SNP) | VAF 21/33 reads (64%) | catalogued as rs374382486; called by muse, mutect2, varscan2
- TP63 | c.762C>T p.N254= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as rs752535926, COSV53206184; called by mutect2, varscan2
- VSTM4 | c.570C>A p.L190= | Silent (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- LINC01993 | n.229T>A | RNA (SNP) | VAF 6/77 reads (8%) | called by muse, mutect2
